TARGET case TARGET-15-SJMPAL004013 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/54f1c96b-eb89-40e0-b985-e3d907f088ef

Demographics
Sex at birth: male; Age at index: 1 years; Vital status: Dead; Days to death: 2,510 days (6.9 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 1.8 years (645 days); Year of diagnosis: 2003; Days to last follow up: 2,510 days (6.9 years).

Follow-up (1 entry)
- Days to follow up: 2,510 days (6.9 years); First event: Relapse; Year of follow up: 2010.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 7.8 ×10³/µL.

Biospecimens (3 samples)
- Samples TARGET-15-SJMPAL004013-04A, TARGET-15-SJMPAL004013-04A.1 (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL004013-15A: Sample type: Fibroblasts from Bone Marrow Normal; Tissue type: Normal; Specimen type: Fibroblasts from Bone Marrow.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 2510
- Protocol: St. Jude
- WBC at Diagnosis: 7.8
- Initial Therapy: ALL
- Karyotype: 46,XY,add(4)(p16),add(12)(p11.2),add(12)(p12)[7]/46,XY[8]
- WHO ALAL Classification: B/M
- WHO Dx: B-ALL
- WHO RL1: B-ALL
- WHO RL2: B/M
